CCDI case PBCBAR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3f493149-b73e-44dc-9f4b-dad606f4b839

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.9 years (6,556 days).

Biospecimens (3 samples)
- Sample 0DOG2T: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOG3C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DOG3M: Tissue type: Tumor; Specimen type: Solid Tissue.
